Somatic mutation profile of tumor specimen TARGET-30-PAUDDZ-01A (aliquot TARGET-30-PAUDDZ-01A-01D) from TARGET case TARGET-30-PAUDDZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.1 years (2,585 days).
Specimen TARGET-30-PAUDDZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6571d142-3d43-420e-9f69-89477ca6c438.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUDDZ-10A (Blood Derived Normal), aliquot TARGET-30-PAUDDZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993fe583-b00e-4f96-ac7c-aac42fc1146d

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLK14 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs1000670989, COSV50069701; called by muse, mutect2, varscan2
- RYR1 | c.5157C>T p.L1719= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs772867465, COSV100614339; called by muse, mutect2, varscan2
- GSE1 | c.*717C>T | 3'UTR (SNP) | VAF 18/90 reads (20%) | catalogued as rs750213040, COSV53674253; called by muse, mutect2, varscan2
- RUNX1 | c.*2220C>A | 3'UTR (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
